MMRF case MMRF_2526 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c969e907-60dc-4cc3-a2ea-ea8794e1ce57

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.5 years (25,377 days); ISS stage: II; Days to last known disease status: 606 days (1.7 years); Days to last follow up: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 260 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): M Protein 4.2 g/dL; Immunoglobulin G 51.7 g/L; Immunoglobulin A 0.239 g/L; Immunoglobulin M 0.168 g/L; Beta 2 Microglobulin 4.76 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.19 mmol/L; Albumin 21.3 g/L; Total Protein 9.5 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 6.96 mg/dL.
- Day 78 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.237 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 8.14 g/L; Immunoglobulin A 0.254 g/L; Immunoglobulin M 0.289 g/L; Beta 2 Microglobulin 2.75 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.44 mmol/L; Albumin 39.1 g/L; Total Protein 6.82 g/dL; Glucose 5.94 mmol/L.
- Day 148 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.745 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.334 g/L; Immunoglobulin M 0.261 g/L; Beta 2 Microglobulin 2.84 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.46 mmol/L; Albumin 36.3 g/L; Total Protein 6.99 g/dL; Glucose 5.94 mmol/L.
- Day 253 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.651 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 5.62 g/L; Immunoglobulin A 0.274 g/L; Immunoglobulin M 0.274 g/L; Beta 2 Microglobulin 3.19 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.37 mmol/L; Albumin 36.7 g/L; Total Protein 6.51 g/dL; Glucose 5.45 mmol/L.
- Day 340 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.958 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 7.12 g/L; Immunoglobulin A 0.345 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.17 mmol/L; Calcium 2.33 mmol/L; Albumin 38.6 g/L; Total Protein 6.46 g/dL; Glucose 5.06 mmol/L.
- Day 431 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.983 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.984 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.354 g/L; Immunoglobulin M 0.366 g/L; Lactate Dehydrogenase 2.75 µkat/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.33 mmol/L; Total Protein 6.56 g/dL; Glucose 5.12 mmol/L.
- Day 515 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.5 mg/dL; Immunoglobulin G 7.19 g/L; Immunoglobulin A 0.449 g/L; Immunoglobulin M 0.511 g/L; Beta 2 Microglobulin 2.57 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.17 mmol/L; Calcium 2.31 mmol/L; Albumin 38.4 g/L; Total Protein 6.36 g/dL; Glucose 5.39 mmol/L.
- Day 606 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.964 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 0.512 g/L; Immunoglobulin M 0.515 g/L; Beta 2 Microglobulin 2.48 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.42 mmol/L; Albumin 38.8 g/L; Total Protein 6.93 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -20: Weight: 65 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_2526_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2526_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
